Somatic mutation profile of tumor specimen ALCH-B1JB-TTP1-A (aliquot ALCH-B1JB-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1JB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.8 years (24,396 days).
Specimen ALCH-B1JB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0f360a2-cb8a-4f6f-b0c6-820886b381a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JB-NB1-A (Blood Derived Normal), aliquot ALCH-B1JB-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8872787-ad15-4aaa-b028-3b39f32411ec

The open-access MAF lists 302 somatic variants for this specimen: 206 protein-altering or splice-affecting, 59 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 59, Intron 19, Nonsense Mutation 10, Frame Shift Del 8, Splice Site 6, 3'UTR 6, RNA 4, 5'UTR 4, In Frame Del 3, 3'Flank 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRIT1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 48/333 reads (14%) | catalogued as rs1554503116, CM034215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADIPOQ | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 289/611 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858968; called by muse, mutect2, varscan2
- AHNAK2 | c.3383G>T p.S1128I | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV100319100; called by muse, mutect2, varscan2
- ALPK1 | c.3186del p.R1063Gfs*24 | Frame Shift Del (DEL) | VAF 47/95 reads (49%) | catalogued as COSV99453216, COSV99455206; called by mutect2, pindel, varscan2
- CASQ2 | c.532+2T>C p.X178_splice | Splice Site (SNP) | VAF 169/374 reads (45%) | catalogued as rs761636557; called by muse, mutect2, varscan2
- CDK14 | c.1171C>T p.H391Y (on ENST00000380050 / NM_001287135.2; = p.H373Y on NM_012395.3) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs867080085; called by muse, mutect2, varscan2
- CFAP45 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1350356083; called by muse, mutect2, varscan2
- COL11A1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371793829; called by muse, mutect2, varscan2
- CREBBP | c.6796G>T p.A2266S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.045); catalogued as rs776123525; called by muse, mutect2, varscan2
- CSMD3 | c.6287C>A p.P2096H (on ENST00000297405 / NM_001363185.1; = p.P1992H on NM_052900.3) | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV52265807; called by muse, mutect2, varscan2
- CT47B1 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 92/118 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV64890734; called by muse, mutect2, varscan2
- CYP2A13 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1382323602; called by muse, varscan2
- DUS4L | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs570732538; called by muse, mutect2, varscan2
- EDNRB | c.367C>T p.P123S (on ENST00000377211 / NM_001201397.1; = p.P33S on NM_000115.5) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100526645; called by muse, mutect2, varscan2
- ERBB4 | c.3919G>T p.V1307L | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV61479830; called by muse, mutect2, varscan2
- FBN2 | c.2960C>A p.T987K | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52500492, COSV52516396; called by muse, mutect2, varscan2
- FCAMR | c.1312A>G p.S438G | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs952838925; called by muse, mutect2, varscan2
- FRMD1 | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.741); catalogued as rs770077391; called by muse, mutect2, varscan2
- GBA3 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101545483; called by muse, mutect2, varscan2
- GUCY1A1 | c.781del p.S261Afs*16 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs1377690573; called by pindel, varscan2
- HK2 | c.781T>G p.W261G | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308873; called by muse, mutect2, varscan2
- HYDIN | c.9410G>A p.R3137H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as rs368611877; called by muse, mutect2
- IL21R | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61969489; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs775624945; called by muse, mutect2, varscan2
- KIR2DL3 | c.997T>C p.Y333H | Missense Mutation (SNP) | VAF 56/831 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs566512398; called by muse, mutect2
- LRP1B | c.8911G>T p.E2971* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV67196924; called by muse, mutect2, varscan2
- MDC1 | c.1218C>G p.D406E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV64527693; called by muse, mutect2, varscan2
- MED24 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373322107; called by muse, mutect2, varscan2
- MOGAT3 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370137222; called by muse, mutect2, varscan2
- MUC16 | c.38650G>C p.E12884Q | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.969); catalogued as rs1440943212, COSV67454159; called by muse, mutect2
- MUC16 | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67501808; called by muse, mutect2, varscan2
- MYO5B | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs202129020; called by muse, mutect2, varscan2
- NCKAP5 | c.3811G>T p.A1271S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531375141, COSV58430260; called by muse, mutect2, varscan2
- NES | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1474753614; called by muse, mutect2
- NXPH1 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68314760; called by muse, mutect2, varscan2
- OR52E2 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762633634; called by muse, mutect2, varscan2
- OR5L2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1201959601, COSV65725305; called by muse, mutect2, varscan2
- OTOF | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 95/374 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.43); catalogued as rs1318800399, COSV99717215; called by muse, mutect2, varscan2
- PANK4 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs375978358; called by muse, mutect2, varscan2
- PCDH17 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 141/231 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100932118; called by muse, mutect2, varscan2
- PLEKHB2 | c.611del p.G204Afs*12 (on ENST00000409279; = p.G203Afs*12 on NM_017958.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 55/194 reads (28%) | catalogued as COSV52178177; called by mutect2, pindel, varscan2
- POTEM | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 74/899 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV101304521; called by muse, mutect2
- PPAN-P2RY11 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs759297854, COSV53453682; called by muse, mutect2, varscan2
- PRDM10 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1178066984, COSV58799354; called by muse, varscan2
- PREX1 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs371681138; called by muse, mutect2, varscan2
- PSMC6 | c.524G>T p.R175L (on ENST00000612399; = p.R161L on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV101471188, COSV101471220; called by muse, mutect2, varscan2
- RPGRIP1 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52858132; called by muse, mutect2, varscan2
- SALL1 | c.1981C>A p.P661T | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1333142713, COSV51755225; called by muse, mutect2, varscan2
- SHROOM2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs765077906; called by muse, mutect2, varscan2
- SLC4A10 | c.1300C>A p.P434T (on ENST00000446997 / NM_001354461.2; = p.P404T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55795783, COSV55796673; called by muse, mutect2, varscan2
- SLC6A3 | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 723/1065 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773275920, COSV54368617; called by muse, mutect2, varscan2
- SLITRK3 | c.2261C>A p.P754H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53847885; called by muse, mutect2, varscan2
- SLITRK5 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 135/271 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100281176; called by muse, varscan2
- SOX8 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53509469; called by muse, mutect2, varscan2
- SPATA31A6 | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV60534489; called by mutect2, varscan2
- STARD9 | c.5340G>T p.W1780C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1046036740; called by muse, mutect2, varscan2
- STXBP2 | c.902+5G>T | Splice Region (SNP) | VAF 111/725 reads (15%) | catalogued as CS106817; called by muse, mutect2, varscan2
- SUPT16H | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201776136; called by muse, mutect2, varscan2
- TNRC6A | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1338867779; called by muse, mutect2, varscan2
- TP53 | c.540del p.E180Dfs*67 | Frame Shift Del (DEL) | VAF 126/234 reads (54%) | catalogued as COSV52795798, COSV52950275, COSV53516148; called by mutect2, pindel, varscan2
- TRDN | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs763375903, COSV62114281; called by muse, mutect2, varscan2
- TRIM48 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201974764; called by muse, mutect2, varscan2
- TSHZ3 | c.1632G>T p.W544C | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53668556; called by muse, mutect2, varscan2
- TTN | c.8116+2C>A p.X2706_splice (on ENST00000591111; = p.X2660_splice on NM_003319.4) | Splice Site (SNP) | VAF 78/175 reads (45%) | catalogued as COSV60053351, COSV60165157; called by muse, mutect2, varscan2
- TYR | c.1015A>T p.S339C | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM971549; called by muse, mutect2, varscan2
- UBR5 | c.7142G>A p.G2381E | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55280725; called by muse, mutect2, varscan2
- VWDE | c.2489G>C p.R830T | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99280340; called by muse, mutect2, varscan2
- ZFR | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs1427030825, COSV54053665; called by muse, mutect2
- ZNF534 | c.1225C>A p.R409S (on ENST00000332323 / NM_001143939.3; = p.R396S on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.329); catalogued as COSV99990095; called by muse, mutect2, varscan2
- ABL2 | c.1046-1G>T p.X349_splice (on ENST00000502732 / NM_007314.4; = p.X334_splice on NM_005158.5) | Splice Site (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- ADIPOR1 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- AGXT | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ALB | c.219T>G p.F73L | Missense Mutation (SNP) | VAF 108/176 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALG6 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPK2 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 84/316 reads (27%) | called by muse, varscan2
- ALX3 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ANKRD24 | c.563C>A p.A188E | Missense Mutation (SNP) | VAF 121/186 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD27 | c.1951T>G p.F651V | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- APOA1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ARHGAP15 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ASPM | c.9721A>G p.R3241G | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AUTS2 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- BAHCC1 | c.6430_6456del p.S2144_N2152del | In Frame Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- BAZ2B | c.2678-2A>T p.X893_splice | Splice Site (SNP) | VAF 84/200 reads (42%) | called by muse, varscan2
- C10orf67 | c.289G>T p.V97L (on ENST00000323327; = p.V98L on NM_153714.3) | Missense Mutation (SNP) | VAF 106/191 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD5 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC102A | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC138 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2
- CDH10 | c.1343A>T p.D448V | Missense Mutation (SNP) | VAF 324/472 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH12 | c.2114C>A p.P705Q | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CETP | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- CGB5 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CLEC10A | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 127/218 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL5A3 | c.3076C>A p.Q1026K | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- COL6A6 | c.5192C>T p.T1731I | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL6A6 | c.5687T>A p.V1896E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- CPQ | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CRISPLD1 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, varscan2
- CROCC2 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DFFB | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DGKB | c.1369A>G p.R457G | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DMBT1 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH17 | c.13104_13112del p.R4369_G4371del | In Frame Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- DNAH7 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- DOCK10 | c.3097G>C p.V1033L | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXOSC9 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FAM135B | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FAM214A | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- FCER2 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- FGF5 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, varscan2
- FOXI3 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 120/413 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF11 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GFAP | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- GLT6D1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GON4L | c.5799C>G p.S1933R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GREB1L | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM5 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADH | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 240/459 reads (52%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- INSR | c.2029+2T>C p.X677_splice | Splice Site (SNP) | VAF 52/1448 reads (4%) | called by muse, mutect2
- ITGA7 | c.959C>T p.A320V (on ENST00000555728; = p.A276V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA7 | c.958G>T p.A320S (on ENST00000555728; = p.A276S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA0319L | c.1224del p.I409Lfs*43 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | called by pindel, varscan2
- KLHL42 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); called by muse, varscan2
- KPRP | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KRTAP10-11 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 113/199 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDLRAD3 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LGALS9 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LRP1 | c.8071G>T p.V2691L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRP1B | c.12031G>T p.G4011W | Missense Mutation (SNP) | VAF 161/448 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAGEB2 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- METTL17 | c.402_410del p.H136_L138del | In Frame Del (DEL) | VAF 43/133 reads (32%) | called by mutect2, pindel, varscan2
- MIER1 | c.1070+1G>A p.X357_splice (on ENST00000355356 / NM_001077701.3; = p.X374_splice on NM_020948.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/48 reads (25%) | called by muse, varscan2
- MRAS | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR8 | c.1832A>G p.N611S | Missense Mutation (SNP) | VAF 106/158 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.31330G>T p.G10444C | Missense Mutation (SNP) | VAF 797/1236 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- MUC17 | c.1211T>C p.L404S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYBL2 | c.1380G>C p.W460C | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYLK2 | c.1561A>G p.I521V | Missense Mutation (SNP) | VAF 198/761 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MYO7A | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NCKAP5L | c.1282_1286del p.S428Gfs*25 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- NDN | c.484A>C p.T162P | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); called by muse, varscan2
- NDUFA10 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 106/246 reads (43%) | called by muse, mutect2, varscan2
- NEIL3 | c.225_229del p.V76Nfs*28 | Frame Shift Del (DEL) | VAF 28/204 reads (14%) | called by mutect2, pindel
- NGF | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NKX2-2 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- NLGN4X | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 107/204 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NOTCH2 | c.4744del p.D1582Tfs*19 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- NPIPB11 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.893); called by muse, varscan2
- NPL | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2T34 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- OR4N2 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51B2 | c.153C>A p.H51Q | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR5A2 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- P2RY14 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 155/487 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PAPPA2 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDH15 | c.5718C>A p.N1906K | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEDS1 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 151/523 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PEG3 | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- PIK3CA | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PLXND1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRAMEF1 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PRAMEF11 | c.528G>T p.R176S | Missense Mutation (SNP) | VAF 118/552 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTBP1 | c.1291G>C p.G431R (on ENST00000349038 / NM_031991.4; = p.G457R on NM_002819.5) | Missense Mutation (SNP) | VAF 219/333 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PTPN3 | c.1900A>G p.M634V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- REG3A | c.55A>T p.M19L | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX8 | c.221G>C p.S74T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ROR1 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RUSC2 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR1 | c.3905G>T p.C1302F | Missense Mutation (SNP) | VAF 110/159 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RYR3 | c.13792T>A p.S4598T (on ENST00000389232; = p.S4599T on NM_001036.6) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.052); called by muse, mutect2
- SERPINB3 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SETBP1 | c.1651T>A p.S551T | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETD2 | c.5099C>T p.A1700V | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SGSM1 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SI | c.3886C>A p.L1296M | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC12A9 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- SLC13A5 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A13 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by mutect2, varscan2
- SLCO5A1 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SNRPB2 | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- SPATC1L | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SRD5A2 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAB2 | c.1583A>T p.Y528F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TBC1D25 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TEP1 | c.2540A>C p.H847P | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TLE4 | c.2211C>A p.F737L | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TLR9 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- TNR | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRDV3 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TRIM55 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 41/358 reads (11%) | called by muse, mutect2, varscan2
- TRIM56 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM64C | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRO | c.1686G>T p.L562F | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TTN | c.56394A>C p.E18798D (on ENST00000591111; = p.E11374D on NM_003319.4) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | PolyPhen probably damaging (0.99); called by muse, mutect2
- UBC | c.1939G>C p.D647H | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- UNC79 | c.5798C>A p.S1933Y (on ENST00000393151 / NM_001346218.2; = p.S1756Y on NM_020818.5) | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- VWA5B1 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- WDR33 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XIRP2 | c.6776A>T p.K2259I (on ENST00000628543; = p.K2434I on NM_152381.6) | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ZBTB20 | c.568A>G p.T190A (on ENST00000474710 / NM_001164342.2; = p.T117A on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZBTB21 | c.1899G>T p.K633N | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZFHX4 | c.1203G>T p.M401I | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF735 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ZNF98 | c.1116T>G p.H372Q | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZZZ3 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ALDH3B2 | c.384G>C p.L128= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.3138C>T p.G1046= | Silent (SNP) | VAF 92/1224 reads (8%) | catalogued as rs141999385; called by muse, mutect2
- ATP6V0B | c.579C>T p.V193= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs372189288; called by muse, mutect2, varscan2
- BIRC6 | c.1005C>T p.L335= | Silent (SNP) | VAF 46/403 reads (11%) | catalogued as rs776183263; called by muse, mutect2, varscan2
- BSN | c.3435G>T p.R1145= | Silent (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- CA13 | c.300C>T p.S100= | Silent (SNP) | VAF 83/292 reads (28%) | catalogued as rs775391404, COSV58797056; called by muse, mutect2, varscan2
- CABIN1 | c.1149A>G p.S383= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as rs772581473; called by muse, mutect2, varscan2
- CCDC166 | c.39C>T p.S13= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1554617045; called by muse, varscan2
- CMKLR1 | c.171C>A p.G57= (on ENST00000312143 / NM_001142344.2; = p.G55= on NM_004072.3) | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as rs1262101956; called by muse, mutect2, varscan2
- CNDP1 | c.1056C>T p.I352= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as rs778293528, COSV62593643; called by muse, mutect2, varscan2
- CNOT3 | c.711G>A p.A237= | Silent (SNP) | VAF 108/208 reads (52%) | catalogued as rs200821584; called by muse, mutect2, varscan2
- CNTROB | c.898A>C p.R300= | Silent (SNP) | VAF 130/347 reads (37%) | catalogued as COSV66608864; called by muse, mutect2, varscan2
- CORO1A | c.609C>T p.I203= | Silent (SNP) | VAF 87/422 reads (21%) | catalogued as rs767224016; called by muse, mutect2, varscan2
- CSMD1 | c.8322G>T p.V2774= (on ENST00000520002; = p.V2773= on NM_033225.6) | Silent (SNP) | VAF 59/101 reads (58%) | catalogued as COSV59333603; called by muse, mutect2, varscan2
- DIO2 | c.456A>T p.S152= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- DUSP22 | c.237C>A p.L79= | Silent (SNP) | VAF 83/412 reads (20%) | called by muse, mutect2, varscan2
- ELMOD3 | c.840C>A p.V280= | Silent (SNP) | VAF 92/628 reads (15%) | catalogued as COSV55706336; called by muse, mutect2, varscan2
- FAM118B | c.606G>T p.V202= | Silent (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- FCRL3 | c.864G>C p.V288= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63839005; called by muse, mutect2, varscan2
- GLP1R | c.420G>A p.Q140= | Silent (SNP) | VAF 88/129 reads (68%) | catalogued as rs907706489; called by muse, mutect2, varscan2
- HS3ST3A1 | c.537C>A p.R179= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as COSV99404235; called by muse, mutect2, varscan2
- HSP90B1 | c.475T>C p.L159= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs1365034485, COSV55357269; called by mutect2, varscan2
- ITGAD | c.1138C>T p.L380= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1152C>A p.A384= | Silent (SNP) | VAF 104/216 reads (48%) | called by muse, mutect2, varscan2
- KLHDC7A | c.852G>T p.R284= | Silent (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.390C>G p.A130= | Silent (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- MBD1 | c.1548G>C p.L516= (on ENST00000269468 / NM_001323950.1; = p.L460= on NM_015844.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/476 reads (22%) | called by muse, mutect2, varscan2
- MBOAT7 | c.30G>C p.V10= | Silent (SNP) | VAF 22/438 reads (5%) | called by muse, mutect2
- MC3R | c.486C>T p.L162= | Silent (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- MEGF6 | c.4536C>T p.P1512= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs748542519; called by muse, mutect2, varscan2
- MON2 | c.1443A>G p.E481= | Silent (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- MUC16 | c.30198A>G p.T10066= | Silent (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- NDN | c.540G>C p.A180= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs762933700; called by muse, varscan2
- NPY2R | c.666T>G p.S222= | Silent (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- OR8H2 | c.93A>G p.L31= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs767181218; called by muse, mutect2, varscan2
- PDS5B | c.3369A>G p.G1123= | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- PEX5L | c.438C>T p.L146= | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- PLCB3 | c.1806C>T p.F602= | Silent (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- PLCE1 | c.3165T>C p.S1055= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1533C>T p.P511= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs760530535, COSV99612258; called by muse, varscan2
- PSG7 | c.1146C>A p.P382= | Silent (SNP) | VAF 81/403 reads (20%) | called by muse, mutect2, varscan2
- PTCD1 | c.981G>T p.V327= | Silent (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- PTCHD4 | c.453C>T p.H151= | Silent (SNP) | VAF 33/48 reads (69%) | called by muse, mutect2, varscan2
- PYGO1 | c.411C>A p.G137= | Silent (SNP) | VAF 60/243 reads (25%) | called by muse, mutect2, varscan2
- RAB2A | c.123A>G p.V41= | Silent (SNP) | VAF 115/246 reads (47%) | called by muse, mutect2, varscan2
- SHOC2 | c.678A>G p.K226= | Silent (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- SKA3 | c.777T>C p.N259= | Silent (SNP) | VAF 66/124 reads (53%) | called by muse, mutect2, varscan2
- SLC30A2 | c.96T>C p.P32= | Silent (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- SLC36A3 | c.765G>T p.L255= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- SOWAHB | c.1026C>T p.P342= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV100530800; called by muse, mutect2, varscan2
- TMX4 | c.393G>T p.L131= | Silent (SNP) | VAF 167/434 reads (38%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.1794G>A p.G598= | Silent (SNP) | VAF 30/127 reads (24%) | called by muse, varscan2
- TSPYL1 | c.870C>A p.S290= | Silent (SNP) | VAF 73/134 reads (54%) | called by muse, mutect2, varscan2
- TTC14 | c.2034T>G p.S678= | Silent (SNP) | VAF 118/329 reads (36%) | called by muse, mutect2, varscan2
- VWA3A | c.897C>A p.T299= | Silent (SNP) | VAF 91/207 reads (44%) | called by muse, mutect2, varscan2
- ZNF329 | c.1521G>A p.R507= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as rs1304377638, COSV100798740; called by muse, mutect2, varscan2
- ZNF536 | c.1612T>C p.L538= | Silent (SNP) | VAF 58/87 reads (67%) | called by muse, mutect2, varscan2
- ZNF607 | c.1605C>T p.C535= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- ZNF805 | c.555T>C p.C185= | Silent (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- ANO5 | c.*13G>C | 3'UTR (SNP) | VAF 99/230 reads (43%) | called by muse, mutect2, varscan2
- C12orf43 | c.-8G>T | 5'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.228-276G>T | Intron (SNP) | VAF 44/267 reads (16%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.228-277G>T | Intron (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.1-65C>T | Intron (SNP) | VAF 12/44 reads (27%) | catalogued as rs926816750; called by mutect2, varscan2
- CCDC140 | n.721C>A | RNA (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- CCDC140 | n.722A>G | RNA (SNP) | VAF 37/173 reads (21%) | catalogued as rs775727370; called by muse, mutect2, varscan2
- CCDC74B | c.296-48C>A | Intron (SNP) | VAF 58/163 reads (36%) | called by muse, mutect2, varscan2
- CCDC74B | c.250+51A>T | Intron (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- CENPX | chr17:82022888 G>C | 5'Flank (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1499-17592C>G | Intron (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- DNAH14 | c.3052-22841G>C | Intron (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- DPYD | c.483+658A>G | Intron (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- EPB41 | c.2496+20C>G | Intron (SNP) | VAF 63/273 reads (23%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8680G>A | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs375175948, CM159750; called by muse, varscan2
- FMNL1 | c.328-61C>G | Intron (SNP) | VAF 15/59 reads (25%) | catalogued as rs572556737; called by muse, mutect2, varscan2
- HGD | c.650-165C>A | Intron (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- HSPA9 | c.1963-37G>T | Intron (SNP) | VAF 149/239 reads (62%) | called by muse, mutect2, varscan2
- IFNAR2 | c.-84+320C>G | Intron (SNP) | VAF 80/165 reads (48%) | catalogued as rs896669663; called by muse, mutect2, varscan2
- IMMT | c.422-10A>G | Intron (SNP) | VAF 86/185 reads (46%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.*69G>T | 3'UTR (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- MCUB | c.*8G>A | 3'UTR (SNP) | VAF 58/95 reads (61%) | catalogued as COSV54461605; called by muse, mutect2, varscan2
- MIR889 | n.46T>G | RNA (SNP) | VAF 37/230 reads (16%) | called by muse, mutect2, varscan2
- NKAIN4 | c.*46A>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- NUDT16 | c.408+52G>A | Intron (SNP) | VAF 135/377 reads (36%) | called by muse, mutect2, varscan2
- NXT2 | chrX:109535955 G>T | 5'Flank (SNP) | VAF 73/116 reads (63%) | called by muse, mutect2, varscan2
- PDGFRA | c.629-5del | Intron (DEL) | VAF 57/278 reads (21%) | called by mutect2, pindel, varscan2
- RAI1 | c.-6C>T | 5'UTR (SNP) | VAF 40/296 reads (14%) | catalogued as rs932414954, COSV99884389; called by muse, mutect2, varscan2
- SLC6A5 | c.*16T>C | 3'UTR (SNP) | VAF 79/457 reads (17%) | called by muse, mutect2, varscan2
- SNORD115-42 | n.43T>C | RNA (SNP) | VAF 58/230 reads (25%) | catalogued as rs747429695; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092141 G>T | 3'Flank (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- TAF10 | c.-1G>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1381501008; called by muse, mutect2
- TAFA2 | c.385-10496A>T | Intron (SNP) | VAF 74/222 reads (33%) | called by muse, varscan2
- TNFAIP8 | c.-149C>A | 5'UTR (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- TOP3B | c.1525+15C>T | Intron (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2, varscan2
- TPSD1 | chr16:1261442 C>G | 3'Flank (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- ZPBP | c.*24G>C | 3'UTR (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
